Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8081, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8081-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

		OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path Report
STOMACH TISSUE CHECKLIST
Specimen type: Gastrectomy
Tumor site: Fundus
Tumor size: 9 x 8 x 1.5 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma
Histologic grade: Moderately differentiated
Tumor extent: Adjacent structures (specify) - Omentum
Lymph nodes: 0/5 positive for metastasis (Regional 0/5)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

Laterality
Fundus

Excision date

Source: NCI Genomic Data Commons file 6e73d65e-f1b3-4516-b60b-744a99911903 (TCGA-BR-8081.9CF967CC-86A9-4750-825B-2C6CB2E40F92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).